Somatic mutation profile of tumor specimen TCGA-24-1419-01A (aliquot TCGA-24-1419-01A-01W-0545-08) from TCGA case TCGA-24-1419, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.0 years (22,659 days).
Specimen TCGA-24-1419-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2f113c-56b3-4829-8b0a-efa725bd701e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1419-10A (Blood Derived Normal), aliquot TCGA-24-1419-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcb59c76-a89f-4683-b852-9c9fb458c0cc

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 742/785 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAD2 | c.583C>T p.P195S (on ENST00000315906 / NM_001145400.2; = p.P267S on NM_139174.4) | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs767727592, COSV51895384; called by muse, mutect2, varscan2
- ADAM29 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 96/119 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV63660339; called by muse, mutect2, varscan2
- AHNAK2 | c.9506C>G p.S3169C | Missense Mutation (SNP) | VAF 70/1398 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100314982; called by muse, mutect2
- B3GNT5 | c.714C>A p.Y238* | Nonsense Mutation (SNP) | VAF 89/304 reads (29%) | catalogued as COSV58476048; called by muse, mutect2, varscan2
- C12orf40 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); catalogued as COSV61137969; called by muse, mutect2, varscan2
- CD84 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 374/1068 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs777494416, COSV60870954; called by muse, mutect2, varscan2
- CFAP100 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs373742550, COSV61502581; called by muse, mutect2, varscan2
- DOCK11 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52247945; called by muse, mutect2, varscan2
- EPHA2 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752235979, COSV64454764; called by muse, mutect2
- FOCAD | c.2516T>A p.F839Y | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV58107847; called by muse, varscan2
- IGHV2-5 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 28/1131 reads (2%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs781802616; called by muse, mutect2
- INTS6L | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV66086433; called by muse, mutect2, varscan2
- LAMB1 | c.4562T>C p.I1521T | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs199646967, COSV55968262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LATS1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 315/677 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53600175; called by muse, mutect2, varscan2
- NLGN4X | c.1092C>A p.N364K | Missense Mutation (SNP) | VAF 110/135 reads (81%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV52037504; called by muse, mutect2, varscan2
- OR2K2 | c.836A>T p.Y279F (on ENST00000374428; = p.Y250F on NM_205859.2) | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57018476; called by muse, mutect2, varscan2
- PCSK5 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65096839; called by muse, mutect2
- PDLIM5 | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 83/121 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58752936; called by muse, mutect2, varscan2
- PLEKHG7 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs199587628, COSV60822849; called by muse, mutect2, varscan2
- PMPCB | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99970986; called by muse, mutect2
- PNKP | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55590743; called by muse, mutect2, varscan2
- RBMS1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV62357324; called by muse, mutect2, varscan2
- ROR2 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65223635; called by muse, mutect2, varscan2
- RSBN1 | c.182C>A p.A61E | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV54735383; called by muse, mutect2, varscan2
- SP100 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 71/246 reads (29%) | catalogued as COSV51010548; called by muse, mutect2, varscan2
- TIMELESS | c.187A>T p.S63C | Missense Mutation (SNP) | VAF 262/906 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1477604728, COSV57515373; called by muse, mutect2, varscan2
- UBE3B | c.2854G>T p.V952F | Missense Mutation (SNP) | VAF 59/543 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61077998; called by muse, mutect2, varscan2
- USP24 | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.971); catalogued as COSV53778874; called by muse, mutect2, varscan2
- UXS1 | c.298G>C p.V100L | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV51676447; called by muse, mutect2, varscan2
- ZNF268 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.023); catalogued as COSV57214490; called by muse, mutect2, varscan2
- IGHG4 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 188/3386 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- SUN1 | c.618_627del p.P207Efs*101 (on ENST00000405266 / NM_001367651.1; = p.P157Efs*31 on NM_025154.6 and 13 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 74/287 reads (26%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.992_997del p.L331_A332del | In Frame Del (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- BTBD8 | c.759C>T p.S253= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs752941229, COSV100730066; called by muse, mutect2
- LRP1 | c.1857G>T p.T619= | Silent (SNP) | VAF 345/1177 reads (29%) | catalogued as rs535216477, COSV99673828, COSV99676422; called by muse, mutect2, varscan2
- MAGEF1 | c.108C>T p.R36= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58634414; called by muse, mutect2, varscan2
- MOB3B | c.387C>T p.I129= | Silent (SNP) | VAF 48/530 reads (9%) | catalogued as COSV51790596; called by muse, mutect2
- SLC2A14 | c.129C>A p.I43= | Silent (SNP) | VAF 25/302 reads (8%) | catalogued as COSV61587173; called by muse, mutect2
- SPANXN2 | c.111C>A p.P37= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as COSV65128505, COSV65129538; called by muse, mutect2, varscan2
- USP13 | c.1986C>G p.A662= | Silent (SNP) | VAF 62/311 reads (20%) | catalogued as COSV55863251; called by muse, mutect2, varscan2
- KLK4 | c.*1C>A | 3'UTR (SNP) | VAF 126/646 reads (20%) | catalogued as COSV100133489; called by muse, mutect2, varscan2
- P4HTM | c.1074-11dup | Intron (INS) | VAF 11/73 reads (15%) | catalogued as rs760453324; called by mutect2, varscan2
